CCDI case PBBLCW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/c103537d-2712-4141-857b-f79c871d7d45

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pigmented dermatofibrosarcoma protuberans: ICD-O-3 morphology code: 8833/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 2.1 years (781 days).

Biospecimens (3 samples)
- Sample 0DBN9O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBNBF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBNBN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
